Somatic mutation profile of tumor specimen TCGA-EY-A1GM-01A (aliquot TCGA-EY-A1GM-01A-12D-A14G-09) from TCGA case TCGA-EY-A1GM, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 60.3 years (22,010 days).
Specimen TCGA-EY-A1GM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3bd87412-3bc3-44e0-ab15-225b9d499499.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A1GM-10A (Blood Derived Normal), aliquot TCGA-EY-A1GM-10A-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15a0a2e0-4ae1-41a5-91e8-47ebd0d283c9

The open-access MAF lists 37 somatic variants for this specimen: 25 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 10, In Frame Del 2, Intron 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1514G>A p.R505H (on ENST00000281708 / NM_001349798.2; = p.R425H on NM_018315.5) | Missense Mutation (SNP) | VAF 19/21 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519896, COSV55901126, COSV55908371, COSV55911517; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 14/15 reads (93%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BTK | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as COSV58123452; called by muse, mutect2
- C7 | c.2519C>T p.A840V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs761687811, COSV57472699; called by muse, mutect2, varscan2
- COG2 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100794547; called by muse, mutect2, varscan2
- DMD | c.1987G>A p.A663T | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV99918234; called by muse, mutect2, varscan2
- FOXP3 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.948); catalogued as rs376715533, COSV100873057; called by muse, mutect2, varscan2
- GPR162 | c.1232G>A p.R411H (on ENST00000311268 / NM_019858.2; = p.R127H on NM_014449.2) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201319224, COSV51832441; called by muse, mutect2, varscan2
- HECTD1 | c.6409C>T p.R2137C | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101237281; called by muse, mutect2, varscan2
- KCNK9 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as rs1340677427, COSV57286527; called by muse, mutect2, varscan2
- MAP2K6 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1158673417, COSV100765016; called by muse, mutect2, varscan2
- MTARC1 | c.328C>A p.P110T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100856213; called by muse, mutect2, varscan2
- MYO19 | c.2399G>A p.R800Q (on ENST00000614623 / NM_001163735.1; = p.R600Q on NM_025109.5) | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs779935312; called by muse, mutect2, varscan2
- PCDHA8 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV65335070; called by muse, mutect2, varscan2
- PRKG1 | c.1732C>G p.P578A | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV100907080; called by muse, mutect2, varscan2
- REV3L | c.2471G>T p.G824V | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as rs781058399, COSV62623026; called by muse, mutect2, varscan2
- SLC16A2 | c.907T>A p.F303I | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV99330249; called by muse, mutect2, varscan2
- SLC9A7 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT tolerated (0.37); PolyPhen benign (0.041); catalogued as rs767024706, COSV60377368; called by muse, mutect2, varscan2
- SOGA3 | c.2246G>A p.R749H | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs866442323, COSV64106008; called by muse, mutect2, varscan2
- SPANXB1 | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 144/1126 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs1375388891; called by muse, mutect2, varscan2
- STX3 | c.200C>G p.P67R | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100276245, COSV55697494; called by muse, mutect2, varscan2
- ZNF106 | c.1820T>A p.L607Q | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99781946; called by muse, mutect2, varscan2
- CCDC136 | c.2581_2613del p.Q861_Q871del | In Frame Del (DEL) | VAF 15/40 reads (38%) | called by mutect2, pindel, varscan2
- CD1C | c.101_103del p.F34del | In Frame Del (DEL) | VAF 24/68 reads (35%) | called by pindel, varscan2
- KANSL1 | c.2089dup p.I697Nfs*10 | Frame Shift Ins (INS) | VAF 36/96 reads (38%) | called by mutect2, pindel, varscan2
- ADAM19 | c.378C>T p.S126= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs1561545470, COSV99975641; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1395A>G p.P465= | Silent (SNP) | VAF 73/108 reads (68%) | catalogued as COSV99835752; called by muse, mutect2, varscan2
- CCDC85A | c.1566T>C p.S522= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as COSV101339328; called by muse, mutect2
- CEP170B | c.612G>A p.G204= (on ENST00000453495; = p.G133= on NM_015005.3) | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV101371357, COSV69026216; called by muse, mutect2
- FAM47C | c.1446C>T p.D482= | Silent (SNP) | VAF 95/203 reads (47%) | catalogued as COSV100792207; called by muse, mutect2, varscan2
- GYS1 | c.645C>T p.A215= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs371721154; called by muse, mutect2, varscan2
- KCNJ12 | c.384C>T p.H128= | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as rs781915873, COSV59172452; called by muse, mutect2, varscan2
- SEMA6D | c.1383C>T p.N461= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as rs1347498228, COSV60381692; called by muse, mutect2, varscan2
- THSD7B | c.1449G>T p.T483= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as COSV99741688; called by muse, mutect2, varscan2
- TNXB | c.6276C>T p.Y2092= (on ENST00000647633; = p.Y1845= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs778894469, COSV64488705; called by muse, mutect2, varscan2
- BAD | c.188-5216G>C | Intron (SNP) | VAF 17/32 reads (53%) | catalogued as COSV100463792; called by muse, mutect2, varscan2
- GATAD2A | c.-90-987A>G | Intron (SNP) | VAF 32/69 reads (46%) | catalogued as rs764442718, COSV99389403; called by muse, mutect2, varscan2
